Gene-level copy-number profile of specimen HCM-WCMC-1284-C67-85A from HCMI case HCM-WCMC-1284-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-1284-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4becafcb-061a-4f37-b621-dfd9553fdf4d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1284-C67-11A (slides); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/677bdae0-4b54-4dda-8cc4-440dfb5d953a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,916; copy number 2: 55,758; copy number 3: 241.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
